Somatic mutation profile of tumor specimen TCGA-DD-A1EF-01A (aliquot TCGA-DD-A1EF-01A-11D-A12Z-10) from TCGA case TCGA-DD-A1EF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.9 years (21,165 days).
Specimen TCGA-DD-A1EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c46f7496-9827-44af-9c4b-b58b191d8c19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EF-10A (Blood Derived Normal), aliquot TCGA-DD-A1EF-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd84f5b8-ff84-4f8c-90ac-3d18650eb2ac

The open-access MAF lists 142 somatic variants for this specimen: 99 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 39, Nonsense Mutation 5, Splice Site 4, RNA 2, Frame Shift Del 2, Intron 1, Splice Region 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG2 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV52949489; called by muse, mutect2, varscan2
- ADCY8 | c.3109G>A p.G1037S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53926759; called by muse, mutect2
- ADGRG4 | c.7522A>G p.M2508V | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs761730115, COSV54966501; called by muse, mutect2, varscan2
- ALAD | c.858G>C p.W286C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV52960824; called by muse, mutect2, varscan2
- ARHGAP44 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.348); catalogued as COSV52402495; called by muse, mutect2, varscan2
- ASXL3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52457856, COSV52479162; called by muse, mutect2, varscan2
- ATG2B | c.688T>A p.W230R | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63425524; called by muse, mutect2
- ATP9A | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.259); catalogued as COSV58771747; called by muse, mutect2
- BLOC1S6 | c.124T>A p.L42M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV55036255; called by muse, mutect2, varscan2
- BRD4 | c.602A>C p.Q201P | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54594824; called by muse, mutect2, varscan2
- BZW2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV51755907, COSV51757631; called by muse, mutect2, varscan2
- C12orf42 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1251170925, COSV59382366; called by muse, mutect2, varscan2
- CAVIN1 | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV63812764; called by muse, mutect2, varscan2
- CBX3 | c.232A>G p.N78D | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV61761863; called by muse, mutect2, varscan2
- CKAP5 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV56373818; called by muse, mutect2
- CLASP2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1174055064, COSV56293676; called by muse, mutect2, varscan2
- CLSTN2 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV71724990; called by muse, mutect2, varscan2
- CLUH | c.664G>A p.G222R (on ENST00000435359; = p.G260R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs1478311187, COSV70930075; called by muse, mutect2, varscan2
- CPT1A | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV55760809; called by muse, mutect2, varscan2
- DDX4 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1430341061, COSV61757310; called by muse, mutect2, varscan2
- DENND5A | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60237835; called by muse, mutect2, varscan2
- DIP2C | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV55178661; called by muse, mutect2, varscan2
- DLEC1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs774060723, COSV57306461; called by muse, mutect2, varscan2
- DMRT2 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV52403673; called by muse, mutect2, varscan2
- DNAH9 | c.10808C>A p.S3603Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV52376264; called by muse, mutect2, varscan2
- DOCK2 | c.4381T>C p.S1461P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56987353; called by muse, mutect2, varscan2
- DSEL | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778536579, COSV59489612; called by muse, mutect2, varscan2
- EHHADH | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51633446; called by muse, mutect2, varscan2
- FAM189B | c.92T>G p.L31R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV56947374; called by muse, mutect2, varscan2
- FDXACB1 | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1555161935, COSV52791095; called by muse, mutect2, varscan2
- FRAS1 | c.9353C>T p.S3118F | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as rs778398446, COSV53646415; called by muse, mutect2, varscan2
- FTO | c.783T>A p.H261Q | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs886052103, COSV67114202; ClinVar: uncertain significance; called by mutect2, varscan2
- FUS | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as rs886051936, COSV54219700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH8 | c.4099G>A p.A1367T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV59198359; called by muse, mutect2
- GPR22 | c.943T>C p.S315P | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1446454467, COSV51764151; called by muse, mutect2, varscan2
- GPRC6A | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs775223423, COSV100113955, COSV59955878; called by muse, mutect2, varscan2
- H3C11 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV58901447; called by muse, mutect2, varscan2
- IDE | c.2654A>T p.H885L | Missense Mutation (SNP) | VAF 70/467 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV56427270; called by muse, mutect2, varscan2
- ITPR1 | c.3914G>A p.R1305Q (on ENST00000354582; = p.R1290Q on NM_002222.7) | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57003414; called by muse, mutect2, varscan2
- JMJD1C | c.4950C>G p.Y1650* | Nonsense Mutation (SNP) | VAF 149/493 reads (30%) | catalogued as COSV59517794; called by muse, mutect2, varscan2
- KATNIP | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV55191515; called by muse, mutect2, varscan2
- KIF20B | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.443); catalogued as COSV53315346; called by muse, mutect2, varscan2
- LILRA1 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV52177404, COSV52184878; called by muse, varscan2
- LPIN2 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55244154; called by muse, mutect2, varscan2
- LRRC31 | c.1601A>G p.E534G | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV52982979; called by muse, mutect2
- LYAR | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58644083; called by muse, mutect2, varscan2
- MMEL1 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 77/115 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56526100; called by muse, mutect2, varscan2
- MROH8 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV54124629; called by muse, mutect2, varscan2
- MTIF2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV55054214; called by muse, mutect2, varscan2
- MTMR6 | c.1666T>G p.S556A | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV67809790; called by muse, mutect2, varscan2
- MTOR | c.4783A>G p.M1595V | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV63878073; called by muse, mutect2, varscan2
- MUC17 | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as rs760718941, COSV100074442, COSV60301132, COSV60302939; called by muse, mutect2, varscan2
- MYLK2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1249774186, COSV101044816; called by muse, mutect2
- MYOF | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770604304, COSV63710529; called by muse, mutect2, varscan2
- NOS1 | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57621645; called by muse, mutect2
- OR6C74 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); catalogued as rs772386317, COSV59607318; called by muse, mutect2, varscan2
- OR6K6 | c.1004A>G p.Q335R (on ENST00000368144; = p.Q311R on NM_001005184.1) | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs559439148, COSV63744886; called by muse, mutect2, varscan2
- PCDHA4 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.253); catalogued as COSV100793267, COSV63543593; called by muse, mutect2, varscan2
- PGLYRP1 | c.283T>A p.Y95N | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50517598; called by muse, mutect2
- PHLDB2 | c.3517A>T p.T1173S (on ENST00000393925 / NM_001134439.2; = p.T1130S on NM_145753.2) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV67316036; called by muse, mutect2, varscan2
- PKNOX2 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV53554584; called by muse, mutect2, varscan2
- PLCB1 | c.1943A>G p.Y648C | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62067962; called by muse, mutect2
- PLEKHG4B | c.3383T>C p.F1128S (on ENST00000283426; = p.F1484S on NM_052909.5) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1375141230, COSV52054960; called by muse, mutect2, varscan2
- PLEKHM1 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV69599420; called by muse, mutect2
- POLQ | c.4121C>T p.P1374L | Missense Mutation (SNP) | VAF 41/377 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as rs1315048990, COSV51750238, COSV51761126; called by muse, mutect2, varscan2
- PPT2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749336768, COSV52998314; called by muse, varscan2
- PROM1 | c.306T>C p.I102= | Splice Region (SNP) | VAF 43/158 reads (27%) | catalogued as COSV71699987; called by muse, mutect2, varscan2
- PTPRC | c.3484A>G p.S1162G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV61420336; called by muse, mutect2, varscan2
- RAPH1 | c.797C>T p.A266V (on ENST00000319170 / NM_213589.3; = p.A318V on NM_203365.4) | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57357590; called by muse, mutect2
- RCN2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV58032010; called by muse, mutect2, varscan2
- RFX7 | c.1682A>G p.K561R (on ENST00000559447 / NM_001368074.1; = p.K658R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as COSV57968688; called by muse, mutect2, varscan2
- SEZ6L | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1569447938, COSV50686414; called by muse, mutect2, varscan2
- SGCZ | c.817T>A p.S273T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66043176; called by muse, mutect2, varscan2
- SIGLEC9 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs781328563, COSV51588150; called by muse, mutect2, varscan2
- SLC12A9 | c.181+1G>T p.X61_splice | Splice Site (SNP) | VAF 125/457 reads (27%) | catalogued as COSV51936869; called by muse, mutect2, varscan2
- SLC1A6 | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV55673898; called by muse, mutect2, varscan2
- SLC22A15 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 144/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65679053; called by muse, mutect2, varscan2
- SMARCA4 | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60798133, COSV60813326; called by muse, mutect2, varscan2
- SMARCA5 | c.2458A>G p.I820V | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV51647264; called by muse, mutect2, varscan2
- SMCHD1 | c.5752A>T p.K1918* | Nonsense Mutation (SNP) | VAF 76/263 reads (29%) | catalogued as COSV57972377; called by muse, mutect2, varscan2
- STK32B | c.203T>A p.V68D | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51512553; called by muse, mutect2, varscan2
- TDRD5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs375929466, COSV54241291; called by muse, mutect2, varscan2
- TENM1 | c.7234T>A p.Y2412N | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64442792; called by muse, mutect2, varscan2
- TG | c.5234-2A>G p.X1745_splice | Splice Site (SNP) | VAF 56/245 reads (23%) | catalogued as COSV55093735; called by muse, mutect2, varscan2
- TMCC1 | c.1244C>A p.P415Q (on ENST00000393238 / NM_001349268.2; = p.P91Q on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61442778; called by muse, mutect2, varscan2
- TMEM102 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53441232; called by muse, mutect2, varscan2
- TTN | c.27147C>G p.S9049R (on ENST00000591111; = p.S8122R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | PolyPhen benign (0.003); catalogued as rs374930292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR5 | c.5927+1G>A p.X1976_splice | Splice Site (SNP) | VAF 202/658 reads (31%) | catalogued as COSV55300009; called by muse, mutect2, varscan2
- UBXN2A | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58337907; called by muse, mutect2, varscan2
- USP24 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as rs1201988757, COSV53778000; called by muse, mutect2, varscan2
- WDR33 | c.2830C>A p.P944T | Missense Mutation (SNP) | VAF 90/137 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV59251749, COSV59255445; called by muse, mutect2, varscan2
- ZFPM2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 26/183 reads (14%) | catalogued as COSV68278055, COSV68292263; called by muse, mutect2, varscan2
- ZNF100 | c.323-1G>C p.X108_splice | Splice Site (SNP) | VAF 7/72 reads (10%) | catalogued as COSV59750029; called by muse, mutect2, varscan2
- ZNF284 | c.460A>C p.K154Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101398908, COSV69691682; called by muse, mutect2
- ZNF721 | c.1693A>G p.R565G (on ENST00000338977; = p.R577G on NM_133474.4) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs782091453, COSV59096995; called by muse, mutect2, varscan2
- ZNF827 | c.3098T>A p.M1033K | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); catalogued as COSV65231896; called by muse, mutect2, varscan2
- LIPI | c.39dup p.Y14Ifs*2 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, varscan2
- PTPN9 | c.1520_1521del p.P507Rfs*35 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, varscan2
- STRAP | c.59del p.L20Wfs*13 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- ANGPT1 | c.1053C>A p.P351= | Silent (SNP) | VAF 35/243 reads (14%) | catalogued as COSV52443853; called by muse, mutect2, varscan2
- ANO2 | c.858C>T p.A286= (on ENST00000356134 / NM_001278597.3; = p.A290= on NM_001278596.3) | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV59042951; called by muse, mutect2, varscan2
- ANO4 | c.501C>T p.A167= (on ENST00000392977 / NM_001286615.2; = p.A132= on NM_178826.4) | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV54613035; called by muse, mutect2, varscan2
- ANP32A | c.369C>T p.C123= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as rs757866606, COSV51189940; called by muse, mutect2, varscan2
- ASXL1 | c.366A>G p.E122= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV60121887; called by muse, varscan2
- ATG14 | c.375A>G p.Q125= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as COSV55958148; called by muse, mutect2, varscan2
- ATR | c.5607G>A p.Q1869= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV63392206; called by muse, mutect2, varscan2
- CCNL2 | c.1425G>A p.E475= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV68767140; called by muse, mutect2, varscan2
- CES3 | c.1461G>A p.E487= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs377447761; called by muse, mutect2, varscan2
- CUBN | c.1848T>C p.C616= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV64726955; called by muse, mutect2, varscan2
- CYLC2 | c.241T>C p.L81= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV66339553; called by muse, mutect2, varscan2
- DSG4 | c.33T>C p.L11= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV57397611; called by muse, mutect2, varscan2
- FAT2 | c.7911C>T p.N2637= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55829147; called by muse, mutect2, varscan2
- HCFC1 | c.2286G>A p.K762= | Silent (SNP) | VAF 82/191 reads (43%) | catalogued as COSV60077574; called by muse, mutect2, varscan2
- JMJD1C | c.6171C>T p.S2057= | Silent (SNP) | VAF 143/478 reads (30%) | catalogued as COSV59517782; called by muse, mutect2, varscan2
- LYST | c.8259G>A p.S2753= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as rs116017878; ClinVar: likely benign; called by muse, mutect2
- MAP7 | c.96G>A p.K32= | Silent (SNP) | VAF 73/290 reads (25%) | catalogued as COSV63421966; called by muse, mutect2, varscan2
- MED12L | c.600C>T p.A200= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV56396711; called by muse, mutect2, varscan2
- MYH1 | c.3588G>A p.L1196= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as COSV56856903; called by muse, mutect2, varscan2
- NCOR2 | c.111C>A p.V37= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- NYAP1 | c.549C>T p.G183= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1199334813, COSV55721677; called by muse, mutect2, varscan2
- OR13C9 | c.492A>G p.V164= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as COSV52243710; called by muse, mutect2, varscan2
- OR6M1 | c.783G>A p.Q261= | Silent (SNP) | VAF 78/152 reads (51%) | catalogued as COSV58434560, COSV58434849; called by muse, mutect2, varscan2
- PCDHA2 | c.1293C>T p.G431= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV65371007; called by muse, mutect2, varscan2
- PCDHGA3 | c.57C>T p.L19= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV54030056; called by muse, mutect2, varscan2
- PFKFB3 | c.432T>C p.N144= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57991568; called by muse, mutect2, varscan2
- RBP3 | c.2299C>T p.L767= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.243A>T p.A81= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV62173548; called by muse, mutect2, varscan2
- SLC15A1 | c.637C>T p.L213= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV64712969; called by muse, mutect2, varscan2
- SPHKAP | c.843T>A p.I281= | Silent (SNP) | VAF 134/1009 reads (13%) | catalogued as COSV60893754; called by muse, mutect2, varscan2
- SRFBP1 | c.1101C>G p.S367= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100232806, COSV59584693; called by muse, mutect2, varscan2
- SUSD1 | c.1899T>A p.S633= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV62585428; called by muse, mutect2, varscan2
- UBE2H | c.75T>C p.V25= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV62921844; called by muse, mutect2, varscan2
- ZNF189 | c.1065G>A p.R355= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV52276931; called by muse, mutect2, varscan2
- ZNF285 | c.1491A>G p.S497= | Silent (SNP) | VAF 107/199 reads (54%) | catalogued as rs548413151, COSV58411169; called by muse, mutect2, varscan2
- ZNF519 | c.849G>A p.Q283= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV73913624; called by muse, mutect2, varscan2
- ZNF681 | c.375A>T p.G125= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV68075618; called by muse, mutect2, varscan2
- ZSCAN1 | c.522T>C p.S174= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV56602638; called by mutect2, varscan2
- ZWINT | c.591G>A p.Q197= | Silent (SNP) | VAF 44/244 reads (18%) | catalogued as rs1449243998, COSV59186358; called by muse, mutect2, varscan2
- DCHS2 | n.733A>G | RNA (SNP) | VAF 17/57 reads (30%) | catalogued as COSV59739208; called by muse, mutect2, varscan2
- DNAH14 | c.749-4196T>C | Intron (SNP) | VAF 34/139 reads (24%) | catalogued as COSV64782588; called by muse, mutect2, varscan2
- FAM169B | n.278G>C | RNA (SNP) | VAF 25/95 reads (26%) | catalogued as COSV60570426; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792453 C>T | 3'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
